Somatic mutation profile of tumor specimen TCGA-HC-7750-01A (aliquot TCGA-HC-7750-01A-11D-2114-08) from TCGA case TCGA-HC-7750, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 50.9 years (18,580 days).
Specimen TCGA-HC-7750-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3877b07-d2ce-45a0-bc34-5948730787fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7750-10A (Blood Derived Normal), aliquot TCGA-HC-7750-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da47c823-96ca-493d-9039-70f003be20d0

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Frame Shift Del 1, Silent 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.760_765del p.F254_E255del | In Frame Del (DEL) | VAF 6/27 reads (22%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- C10orf90 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52950723; called by muse, mutect2
- C7orf33 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1323963341, COSV61022747; called by muse, mutect2, varscan2
- CYP7A1 | c.215T>C p.M72T | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.242); catalogued as COSV56962721; called by muse, mutect2, varscan2
- GPR150 | c.133C>G p.R45G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV66168189; called by muse, mutect2, varscan2
- GRIN2A | c.2917G>T p.D973Y | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58023981, COSV58053039; called by muse, mutect2
- OTUB1 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | catalogued as COSV55357740; called by muse, mutect2, varscan2
- PLEKHG1 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV62045610; called by muse, mutect2, varscan2
- PPP1R21 | c.1462A>G p.S488G | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54282540; called by muse, mutect2, varscan2
- SPATA45 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV60571493; called by muse, mutect2, varscan2
- VWA8 | c.1667A>C p.E556A | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.186); catalogued as COSV55693481; called by muse, mutect2, varscan2
- CAP1 | c.899del p.F300Sfs*42 | Frame Shift Del (DEL) | VAF 16/113 reads (14%) | called by mutect2, pindel, varscan2
- CCDC180 | c.204G>A p.Q68= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV63827627, COSV63829676; called by muse, mutect2
